MMRF case MMRF_1641 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/866b0a16-330a-45f9-8245-d70afdf8a4d7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 529 days (1.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.4 years (25,712 days); ISS stage: III; Days to last known disease status: 529 days (1.4 years); Days to last follow up: 529 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 146 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 20 days; Days to treatment end: 506 days (1.4 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 34 days; Days to treatment end: 145 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 211 days; Days to treatment end: 470 days (1.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 529.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 0.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 24.8 mg/dL; Beta 2 Microglobulin 23.3 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 90 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 61.4 mg/dL; Hemoglobin 5.46 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.6 g/dL; Glucose 5.34 mmol/L.
- Day 189 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 46.2 mg/dL; Immunoglobulin G 3.13 g/L; Immunoglobulin A 12 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 4.18 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 6.66 mmol/L.
- Day 267 (ECOG 1): M Protein 7.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 22.8 mg/dL; Immunoglobulin G 2.38 g/L; Immunoglobulin A 7.03 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 3.15 µg/mL; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.
- Day 351 (ECOG 1): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 25.9 mg/dL; Immunoglobulin G 1.82 g/L; Immunoglobulin A 7.36 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.24 mmol/L.
- Day 435 (ECOG 1): M Protein 1.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 60.5 mg/dL; Immunoglobulin G 1.57 g/L; Immunoglobulin A 12.1 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.7 g/dL; Glucose 3.96 mmol/L.

Other clinical attributes
- Day -2: Weight: 58 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1641_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1641_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
